Somatic mutation profile of tumor specimen TCGA-96-A4JL-01A (aliquot TCGA-96-A4JL-01A-11D-A257-08) from TCGA case TCGA-96-A4JL, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.5 years (28,686 days).
Specimen TCGA-96-A4JL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc21509c-70c0-44ee-8a00-51541483875e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-96-A4JL-10A (Blood Derived Normal), aliquot TCGA-96-A4JL-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/895880e5-7b19-42e1-96c6-315b0ae8fe8d

The open-access MAF lists 59 somatic variants for this specimen: 45 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 1, In Frame Del 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 19/113 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs121908596, CM080433, COSV61068347, COSV61068483; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANK2 | c.4270C>T p.P1424S | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769015777, COSV52193536; called by muse, mutect2, varscan2
- C6orf226 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100491730; called by muse, mutect2
- CAMSAP2 | c.2857T>C p.S953P (on ENST00000236925 / NM_001297707.2; = p.S942P on NM_203459.3) | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99373593; called by muse, mutect2, varscan2
- CDC73 | c.1340T>A p.V447E | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100813907; called by muse, mutect2, varscan2
- CDH9 | c.2318G>A p.R773H | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.581); catalogued as rs553402369, COSV50304892; called by muse, mutect2, varscan2
- CENPT | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs778229845, COSV99535190; called by muse, mutect2, varscan2
- DCAF12L1 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs768239477, COSV100948355; called by muse, mutect2, varscan2
- FADD | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs1174353918, COSV100096684; called by muse, mutect2, varscan2
- FAM237A | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200894319, COSV101405585; called by muse, mutect2, varscan2
- IGFBP4 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs764155216, COSV54097235; called by muse, mutect2, varscan2
- KIF11 | c.1556G>C p.R519P | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99585930; called by muse, mutect2, varscan2
- KRT28 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs750808725, COSV100137598; called by muse, mutect2, varscan2
- LILRA4 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.402); catalogued as rs763023157, COSV52493499; called by muse, mutect2, varscan2
- LMTK2 | c.2480G>T p.R827L | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99807092; called by muse, mutect2, varscan2
- MAP10 | c.2599G>T p.A867S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.591); catalogued as COSV101406521; called by muse, mutect2, varscan2
- MGA | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 49/373 reads (13%) | catalogued as COSV99580455; called by muse, mutect2, varscan2
- MTIF2 | c.2071G>A p.D691N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99703204; called by muse, mutect2, varscan2
- MYH1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs779598062, COSV56846716; called by muse, mutect2, varscan2
- NELL2 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.524); catalogued as COSV100419924; called by muse, mutect2, varscan2
- NNT | c.2877-2A>T p.X959_splice | Splice Site (SNP) | VAF 38/214 reads (18%) | catalogued as COSV99239123; called by muse, mutect2, varscan2
- NOL4 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867543044, COSV52344961; called by muse, mutect2
- OBSCN | c.17612C>T p.P5871L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99480554; called by muse, mutect2
- OR11H6 | c.848G>C p.G283A | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as COSV100209860, COSV100209866; called by muse, mutect2
- PCDH19 | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); catalogued as COSV99720108; called by muse, mutect2, varscan2
- PLXNA4 | c.1708G>A p.V570I | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.482); catalogued as rs752672355, COSV58109556; called by muse, mutect2, varscan2
- PPTC7 | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as rs747451267, COSV100845715; called by muse, mutect2, varscan2
- PRKCG | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV99669204; called by muse, mutect2, varscan2
- PSME3 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs778805863, COSV53199277; called by muse, mutect2, varscan2
- RAB6C | c.128A>T p.Q43L | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV101308522; called by muse, mutect2, varscan2
- SLC12A8 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360778251, COSV100102613; called by muse, mutect2
- SSMEM1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs191908225, COSV52833532; called by muse, mutect2, varscan2
- SYT9 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs567812209, COSV59626171; called by muse, mutect2, varscan2
- TNKS2 | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV100861118; called by muse, mutect2
- TRAF3 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 36/139 reads (26%) | catalogued as COSV100693643; called by muse, mutect2, varscan2
- UBR4 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.248); catalogued as COSV100920568; called by muse, mutect2, varscan2
- USP6NL | c.649A>T p.K217* | Nonsense Mutation (SNP) | VAF 23/129 reads (18%) | catalogued as COSV99509790; called by muse, mutect2, varscan2
- WDR90 | c.4455G>A p.W1485* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | catalogued as COSV99553644; called by muse, mutect2, varscan2
- ZDHHC9 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 45/203 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV100852248; called by muse, mutect2, varscan2
- ZNF836 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 10/317 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100441032, COSV59081035; called by muse, mutect2
- ZXDB | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV100885960; called by muse, mutect2, varscan2
- GSE1 | c.2785del p.D929Mfs*38 | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | called by mutect2, pindel, varscan2
- SYNGAP1 | c.1740_1741del p.R581Gfs*36 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- TALDO1 | c.270_272del p.L90del | In Frame Del (DEL) | VAF 29/245 reads (12%) | called by pindel, varscan2
- UBC | c.1922dup p.E642Gfs*6 | Frame Shift Ins (INS) | VAF 50/324 reads (15%) | called by pindel, varscan2
- AMPD2 | c.153C>T p.A51= | Silent (SNP) | VAF 36/200 reads (18%) | catalogued as COSV99857875; called by muse, mutect2, varscan2
- AUH | c.879T>C p.I293= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV100342520, COSV57862476; called by muse, mutect2, varscan2
- MUC17 | c.2313T>A p.P771= | Silent (SNP) | VAF 100/627 reads (16%) | catalogued as COSV100073934; called by muse, mutect2, varscan2
- NPTX2 | c.1143C>T p.R381= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs776156518, COSV55716965; called by muse, mutect2
- NSDHL | c.315G>A p.A105= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as rs781847194, COSV100938667; called by muse, mutect2, varscan2
- NUP155 | c.450G>A p.V150= (on ENST00000231498 / NM_153485.3; = p.V91= on NM_004298.4) | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV99193567; called by muse, mutect2, varscan2
- OR5D18 | c.660G>A p.A220= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as rs779827741, COSV61737938, COSV61738052; called by muse, mutect2, varscan2
- PCDHGA6 | c.1497G>A p.A499= | Silent (SNP) | VAF 36/360 reads (10%) | catalogued as COSV99541043; called by muse, mutect2
- PLTP | c.570C>T p.H190= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs755507721, COSV100819106; called by muse, mutect2, varscan2
- SCRIB | c.3444C>T p.D1148= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs150206819; called by muse, mutect2, varscan2
- TCEAL3 | c.111C>T p.D37= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV99685284; called by muse, mutect2, varscan2
- TRABD | c.813G>A p.A271= | Silent (SNP) | VAF 31/150 reads (21%) | catalogued as rs145839914; called by muse, mutect2, varscan2
- TRAF3 | c.669A>C p.S223= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as COSV61025769; called by muse, mutect2, varscan2
- MAGEA4 | c.-121C>A | 5'UTR (SNP) | VAF 9/78 reads (12%) | catalogued as COSV99367560; called by muse, varscan2
